Gene-level copy-number profile of tumor specimen TCGA-EE-A2M6-06A from TCGA case TCGA-EE-A2M6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 64.4 years (23,507 days).
Specimen TCGA-EE-A2M6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.36fdcaff-5f89-4db2-8dc6-2c96115ae24f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2M6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6f72ae3-58c0-41b1-abbe-b2d203400b0e

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 17,106; copy number 3: 14,420; copy number 4: 9,029; copy number 5: 15,795; copy number 6: 565; copy number 7: 149; copy number 8: 754; copy number 9: 650; copy number 10: 1,274; copy number 11: 54; copy number 43: 11; copy number 66: 4; copy number 72: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2M6-06A-12D-A191-01): tumor purity 0.95, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 75 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:15,970,003–16,697,479, 17 genes, copy number 11: AC090946.1, GALNT15, AC090953.2, DPH3, OXNAD1, AC090953.1, RFTN1, AC090948.1, AC090948.2, AC090948.3, AC090948.4, AC010727.1, LINC00690, AC010139.1, DAZL, AC091493.1, CDYLP1.
- chr3:69,535,664–69,968,336, 5 genes, copy number 11: AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P.
- chr3:88,948,142–91,513,775, 12 genes, copy number 11: ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr7:144,849,755–148,420,998, 20 genes, copy number 11 (within-gene range 9–11): RN7SKP174, EI24P4, AC073310.1, RPL7P59, AC004911.1, DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2, RNU6-1184P, RNA5SP249, RN7SL456P.
- chr8:127,663,280–129,683,770, 21 genes, copy number 43–72 (within-gene range 5–72): AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
